Somatic mutation profile of tumor specimen TARGET-30-PARPGU-01A (aliquot TARGET-30-PARPGU-01A-01D) from TARGET case TARGET-30-PARPGU, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 3.1 years (1,145 days).
Specimen TARGET-30-PARPGU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49e573af-a116-4b59-8a77-395c8fa2775c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARPGU-10A (Blood Derived Normal), aliquot TARGET-30-PARPGU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65b74c93-c5d4-4790-93a8-3325b6f941ea

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLVS1 | c.701C>A p.T234K | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as COSV57983160; called by muse, mutect2
- MYOT | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV53513566; called by muse, mutect2, varscan2
- RARA | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54191803, COSV54193672, COSV99565431; called by muse, mutect2
- SHLD1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV57439710; called by muse, mutect2
- CEACAM20 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- CKAP5 | c.3012G>T p.E1004D | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- GPR179 | c.2246G>A p.G749D (on ENST00000621958; = p.G748D on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IGHA2 | c.348G>A p.L116= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
